ORGANOID case 36 — Pancreas Cancer Organoid Profiling (ORGANOID-PANCREATIC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/490344a3-9367-42cb-b109-8562eed90bdf

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Adenocarcinoma, NOS: Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Pancreas, NOS; AJCC pathologic stage: Stage IIB.

Biospecimens (4 samples)
- Sample S10: Sample type: Next Generation Cancer Model; Tissue type: Normal; Specimen type: Buffy Coat.
- Samples S11, S166, S64 (3 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Specimen type: 3D Organoid.
